Gene-level copy-number profile of tumor specimen TCGA-BB-8601-01A from TCGA case TCGA-BB-8601, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 84.1 years (30,721 days).
Specimen TCGA-BB-8601-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.6000fd2a-733d-4e89-a2f5-f4f69228600f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BB-8601-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e41dbbdb-b045-4c6c-bf7a-af61feae6922

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,421; copy number 2: 21,433; copy number 3: 16,043; copy number 4: 17,517; copy number 5: 1,171; copy number 6: 1,088; copy number 7: 71; copy number 10: 62.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BB-8601-01A-11D-2390-01): tumor purity 0.9, ploidy 1.63, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,392 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:239,972,787–245,134,090, 103 genes, copy number 6 (broad region; genes not listed).
- chr1:245,206,444–245,283,089, 2 genes, copy number 6: KIF26B-AS1, DNAJC19P8.
- chr3:110,682,286–198,222,513, 1,587 genes, copy number 5–6 (broad region; genes not listed).
- chr7:36,854,361–38,932,394, 45 genes, copy number 5 (within-gene range 4–5): ELMO1, MIR1200, ELMO1-AS1, RPS17P13, RNU6-565P, RPS10P14, AC078843.1, Y_RNA, NECAP1P1, GPR141, EPDR1, GPR141BP, AC018634.1, NME8, SFRP4, STARD3NL, TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1, AMPH, RN7SL83P, KRT8P20, FAM183BP, VPS41.
- chr8:107,857,589–116,325,062, 61 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr9:60,914,407–63,762,824, 74 genes, copy number 6 (broad region; genes not listed).
- chr19:27,638,483–31,147,981, 70 genes, copy number 6–10 (broad region; genes not listed).
- chr19:31,167,457–31,225,143, 1 gene, copy number 6 (within-gene range 2–6): LINC01791.
- chr22:19,171,395–26,780,893, 449 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
